Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9LN, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9LN-01A (Primary Tumor).

[page 1 of 3]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 50 g, Volume: 45 ml, Size: 3.6 x 5 x 4 cm. Adherent seminal vesicles and deferent duct: right side: 2.5 cm, left side: 3.5 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the right recto-lateral surface a 1.5 x 0.7 cm measuring tissue defect marked with yellow ink. On the left recto-lateral surface a 3 x 2 cm measuring tissue defect marked with yellow ink. On the anterior side a 3.3 x 2 cm measuring tissue defect marked with black ink. Total of the cross sections: 2 cm.
2. (Lymph nodes, right side): 9 x 3.5 x 1 cm measuring adipose tissue containing 5 nodes measuring up to 4.5 cm.
3. (Lymph nodes, left side): 9 x 4 x 0.5 cm measuring adipose tissue containing 4 nodes measuring up to 8 cm.

Microscopy:

1. Apex right and left: Right 7 tissue blocks, left 6 tissue blocks (total 13 tissue blocks). 4 cross sections: Right 20 tissue blocks, left 18 tissue blocks (total 38 tissue blocks). Basis right and left: Right 4 tissue blocks, left 6 tissue blocks (total 10 tissue blocks). Seminal vesicles right and left: Right 3 tissue blocks, left 3 tissue blocks (total 6 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Frozen lymph nodes right: 11 tissue blocks.
3. Frozen lymph nodes left: 6 tissue blocks.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/20/14

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 80%, Gleason 4: 20%). Tumor involves both lobes with the main focus on the left side. Maximum tumor diameter: 45 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 1 tissue blocks (maximum invasion length 0.1 mm, maximal invasion depth 0.1 mm). Positive surgical margin in 3 blocks (contact area 3 x 0.4 mm; Gleason 5). Tumor-free peri-urethral resection margin.

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free seminal vesicles and deferent ducts.

2. (Lymph nodes, right side): Four lymph node metastases (3.8 mm) in five lymph nodes(4/5).
3. (Lymph nodes, left side): Two lymph node metastases (4 mm) in five lymph nodes (2/5).

[page 2 of 3]
Tumor classification

(in consideration of the intraoperative frozen-section and immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5: 80%, Gleason 4: 20%), maximum tumor diameter: 45 mm, tumor volume approx. 27 ml (Gleason 4: 5.4 ml, Gleason 5: 21.6 ml), pN1 (6/10), L1, V0, R1

Comments:

Positive surgical margin in tissue blocks AL1A, AL2A, BL3.

Tumor infiltration into seminal vesicles in tissue blocks SBL1, BL1B, BL2B,

Tumor infiltration into peri-prostatic adipose tissue in tissue block SBL1.

The preceding intraoperative frozen section revealed negative surgical margin of the urethra.

Immunohistochemical analyses (D2-40, CD31) on tissue block SBL1 revealed lymphatic invasion but no venous invasion.

One macroscopic image for tumor mapping.

*Per dx discrepancy form, TCGA
tumor is Gleason 5+5*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason 5+4	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Gleason 5+5	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Frozen sample tissue block submitted to TCGA has a different Gleason score than the frozen tissue block that was used for diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature Date

Source: NCI Genomic Data Commons file 819d5cb8-3ba1-4b4c-88f6-b0905713fe48 (TCGA-ZG-A9LN.3B5E5429-7D1E-4AD2-8329-DC784D412393.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).